Somatic mutation profile of tumor specimen TCGA-29-1785-01A (aliquot TCGA-29-1785-01A-01W-0633-09) from TCGA case TCGA-29-1785, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 55.9 years (20,417 days).
Specimen TCGA-29-1785-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4230a14f-3b2e-470a-99b2-a9d948869813.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-29-1785-10A (Blood Derived Normal), aliquot TCGA-29-1785-10A-01W-0634-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b217fc25-f3d0-422d-95b3-d28e3d3ec084

The open-access MAF lists 72 somatic variants for this specimen: 54 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 16, Frame Shift Del 4, Splice Site 4, Frame Shift Ins 3, Nonsense Mutation 2, 5'Flank 1, In Frame Ins 1, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.920-2A>G p.X307_splice | Splice Site (SNP) | VAF 110/141 reads (78%) | hotspot (GDC flag); catalogued as rs397516439, COSV52693974, COSV52706655, COSV52945558, COSV53066011; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB10 | c.1750A>G p.I584V | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.315); catalogued as rs754809765, COSV60620236; called by muse, mutect2, varscan2
- ANKRD35 | c.1961G>A p.R654Q | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV62909847; called by muse, mutect2, varscan2
- C5 | c.2353C>G p.Q785E | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV56325038; called by muse, mutect2, varscan2
- CABP4 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.326); catalogued as rs1445541750, COSV57797503; called by muse, mutect2, varscan2
- CAMTA1 | c.1687A>G p.T563A | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV57887277; called by muse, mutect2, varscan2
- CEP63 | c.1912A>G p.M638V | Missense Mutation (SNP) | VAF 86/187 reads (46%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1405333649, COSV59674953; called by muse, mutect2, varscan2
- CSF2RA | c.79C>T p.L27= | Splice Region (SNP) | VAF 17/57 reads (30%) | catalogued as COSV62623916; called by muse, mutect2, varscan2
- CSMD3 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52129199; called by muse, varscan2
- DHX57 | c.347G>C p.R116P | Missense Mutation (SNP) | VAF 88/252 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs535416668, COSV54883323; called by muse, mutect2, varscan2
- DNAH3 | c.10597G>A p.A3533T | Missense Mutation (SNP) | VAF 86/213 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV54509889; called by muse, mutect2, varscan2
- DNAH7 | c.4781A>T p.Q1594L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56756228; called by muse, mutect2, varscan2
- ECE1 | c.1832A>C p.H611P | Missense Mutation (SNP) | VAF 39/48 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99942312; called by muse, mutect2
- FGA | c.2367C>A p.D789E | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57394113; called by muse, mutect2, varscan2
- GATAD2B | c.1335G>A p.M445I | Missense Mutation (SNP) | VAF 149/354 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV64083568, COSV64086068; called by muse, mutect2, varscan2
- GPR156 | c.2432C>T p.P811L | Missense Mutation (SNP) | VAF 12/285 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100251706; called by muse, mutect2
- INSRR | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV63871574, COSV63876415; called by muse, mutect2, varscan2
- KATNIP | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 8/12 reads (67%) | catalogued as rs748762874, COSV55175843; called by muse, varscan2
- KCNQ1 | c.1428G>T p.M476I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV50102317; called by muse, mutect2, varscan2
- KRT10 | c.1071G>C p.Q357H | Missense Mutation (SNP) | VAF 67/89 reads (75%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV54088988; called by muse, mutect2, varscan2
- LANCL2 | c.205-1G>C p.X69_splice | Splice Site (SNP) | VAF 37/73 reads (51%) | catalogued as COSV54648281; called by muse, mutect2, varscan2
- LRP1 | c.7044G>A p.W2348* | Nonsense Mutation (SNP) | VAF 39/94 reads (41%) | catalogued as rs1555186029, COSV54505010; called by muse, mutect2, varscan2
- MAPRE2 | c.396+1G>T p.X132_splice | Splice Site (SNP) | VAF 30/65 reads (46%) | catalogued as COSV55818049; called by muse, mutect2, varscan2
- MED12L | c.5378C>A p.P1793H | Missense Mutation (SNP) | VAF 111/213 reads (52%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.99); catalogued as COSV56372219; called by muse, mutect2, varscan2
- METTL15 | c.407+1G>A p.X136_splice | Splice Site (SNP) | VAF 30/82 reads (37%) | catalogued as rs755882884, COSV57718734; called by muse, mutect2, varscan2
- MYH11 | c.5683C>T p.R1895C | Missense Mutation (SNP) | VAF 204/440 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs992494235, COSV55545305; called by muse, mutect2, varscan2
- PCDHB7 | c.1778A>G p.D593G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99177359; called by muse, mutect2
- PGM2 | c.568A>G p.K190E | Missense Mutation (SNP) | VAF 16/235 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs977162803, COSV101126644; called by muse, mutect2
- PIWIL1 | c.1315C>G p.R439G | Missense Mutation (SNP) | VAF 139/353 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55345072, COSV55351997; called by muse, mutect2, varscan2
- PLA2G15 | c.25C>G p.R9G | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV54722568; called by muse, mutect2, varscan2
- PLBD2 | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV55105985; called by muse, mutect2, varscan2
- PLEKHA7 | c.1088C>A p.S363Y | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as COSV63044477; called by muse, mutect2, varscan2
- RHOBTB3 | c.644C>G p.S215C | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV66101374; called by muse, mutect2, varscan2
- RPLP1 | c.309G>C p.E103D | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.257); catalogued as COSV53006388; called by muse, mutect2, varscan2
- RUVBL2 | c.1042A>G p.I348V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as rs1232457303, COSV55484546; called by muse, mutect2, varscan2
- SGCD | c.29G>A p.R10Q (on ENST00000435422 / NM_001128209.2; = p.R11Q on NM_000337.5) | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.968); catalogued as rs752548592, COSV61903106; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC40A1 | c.1270C>A p.P424T | Missense Mutation (SNP) | VAF 80/174 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV53722294; called by muse, mutect2, varscan2
- SPHKAP | c.3626G>T p.S1209I | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.36); catalogued as COSV60871932; called by muse, mutect2, varscan2
- SVEP1 | c.1823C>G p.A608G | Missense Mutation (SNP) | VAF 159/417 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV57031672; called by muse, mutect2, varscan2
- TPP1 | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 52/93 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs773455971, COSV54993681, COSV54994759; ClinVar: benign; called by muse, mutect2, varscan2
- TTN | c.98101G>C p.D32701H (on ENST00000591111; = p.D25277H on NM_003319.4) | Missense Mutation (SNP) | VAF 30/89 reads (34%) | PolyPhen probably damaging (0.943); catalogued as COSV59939720; called by muse, mutect2, varscan2
- TUB | c.1090C>T p.R364C (on ENST00000299506 / NM_177972.3; = p.R419C on NM_003320.4) | Missense Mutation (SNP) | VAF 113/251 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1345174025, COSV55107059; called by muse, mutect2, varscan2
- VWF | c.780dup p.L261Afs*42 | Frame Shift Ins (INS) | VAF 6/60 reads (10%) | catalogued as rs760130928; called by pindel, varscan2
- WDR20 | c.437T>A p.L146Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV54471147; called by muse, mutect2, varscan2
- WDR64 | c.1993G>A p.G665R | Missense Mutation (SNP) | VAF 127/205 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63793595; called by muse, mutect2, varscan2
- ZNF335 | c.3310G>C p.A1104P | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.376); catalogued as COSV59816685; called by muse, mutect2, varscan2
- ZNF485 | c.865del p.Q289Rfs*150 | Frame Shift Del (DEL) | VAF 28/70 reads (40%) | catalogued as COSV62423845; called by mutect2, pindel, varscan2
- ZNF516 | c.542G>A p.S181N | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.027); catalogued as rs1239087858, COSV71586800; called by muse, mutect2, varscan2
- CCDC142 | c.2027del p.L676Cfs*32 (on ENST00000393965 / NM_001365575.2; = p.L669Cfs*32 on NM_032779.4) | Frame Shift Del (DEL) | VAF 33/89 reads (37%) | called by mutect2, pindel, varscan2
- PAX1 | c.501dup p.S168Efs*40 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | called by mutect2, pindel, varscan2
- RESF1 | c.78_100del p.Q26Hfs*13 | Frame Shift Del (DEL) | VAF 28/77 reads (36%) | called by mutect2, pindel, varscan2
- SLC25A4 | c.415_437del p.T139Qfs*7 | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | called by mutect2, pindel, varscan2
- SNX18 | c.1245dup p.A416Rfs*5 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by pindel, varscan2
- WASHC4 | c.2616_2618dup p.F873dup | In Frame Ins (INS) | VAF 32/97 reads (33%) | called by mutect2, pindel, varscan2
- ADGRB3 | c.2928A>G p.T976= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as COSV53238229; called by muse, mutect2, varscan2
- ATP10B | c.2916G>A p.K972= | Silent (SNP) | VAF 83/102 reads (81%) | catalogued as COSV59146203; called by muse, mutect2, varscan2
- CLEC4D | c.255T>C p.P85= | Silent (SNP) | VAF 29/62 reads (47%) | catalogued as COSV55228380; called by muse, mutect2, varscan2
- DNAH1 | c.7815C>T p.Y2605= | Silent (SNP) | VAF 11/154 reads (7%) | catalogued as rs764179591, COSV101327031; called by muse, mutect2
- DOLPP1 | c.144G>C p.V48= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as COSV59910120; called by muse, mutect2, varscan2
- GCN1 | c.6502A>C p.R2168= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV56105146; called by muse, mutect2, varscan2
- HSD17B3 | c.684A>G p.P228= | Silent (SNP) | VAF 82/184 reads (45%) | catalogued as COSV64556458; called by muse, mutect2, varscan2
- KCNJ3 | c.501C>T p.I167= | Silent (SNP) | VAF 46/99 reads (46%) | catalogued as COSV54533257; called by muse, mutect2, varscan2
- MED25 | c.342C>T p.I114= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs367931150; called by muse, mutect2, varscan2
- MTPAP | c.507G>A p.L169= | Silent (SNP) | VAF 39/306 reads (13%) | catalogued as COSV53931890; called by muse, mutect2, varscan2
- NPHS1 | c.3579C>T p.Y1193= | Silent (SNP) | VAF 54/124 reads (44%) | catalogued as rs747950877, COSV62286104; called by muse, mutect2, varscan2
- PLAAT4 | c.276C>T p.I92= | Silent (SNP) | VAF 97/220 reads (44%) | catalogued as COSV55372853; called by muse, mutect2, varscan2
- PPL | c.3627C>G p.L1209= | Silent (SNP) | VAF 61/82 reads (74%) | catalogued as rs773016482, COSV52166556, COSV52174031; called by muse, mutect2, varscan2
- RPTOR | c.1065G>A p.R355= | Silent (SNP) | VAF 8/158 reads (5%) | catalogued as COSV100157206; called by muse, mutect2
- SIRT7 | c.774C>A p.A258= | Silent (SNP) | VAF 16/18 reads (89%) | catalogued as COSV58710902; called by muse, mutect2, varscan2
- TEX43 | c.267T>C p.L89= | Silent (SNP) | VAF 44/133 reads (33%) | catalogued as COSV64035986; called by muse, mutect2, varscan2
- CLLU1 | chr12:92421162 T>A | 5'Flank (SNP) | VAF 167/330 reads (51%) | catalogued as COSV65902891; called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92472459 C>T | 3'Flank (SNP) | VAF 64/136 reads (47%) | called by muse, mutect2, varscan2
